Somatic mutation profile of tumor specimen TARGET-10-PANTZE-09B (aliquot TARGET-10-PANTZE-09B-01D) from TARGET case TARGET-10-PANTZE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,285 days).
Specimen TARGET-10-PANTZE-09B: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 407858af-a26f-431f-b451-64dcd02b8d5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANTZE-10A (Blood Derived Normal), aliquot TARGET-10-PANTZE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44519bcd-c12f-4c36-890e-b196f4e2a022

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, 5'Flank 2, Intron 2, Nonsense Mutation 2, 3'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DISP2 | c.411G>T p.W137C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51130879; called by muse, mutect2, varscan2
- MYO15A | c.4891G>A p.E1631K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756175347; called by muse, mutect2
- NUDCD1 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV53457772; called by muse, mutect2, varscan2
- OTUD6A | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV100611071; called by muse, mutect2, varscan2
- PDE6C | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs145216599; called by muse, mutect2, varscan2
- PHF8 | c.2977C>T p.R993C (on ENST00000357988 / NM_001184896.1; = p.R957C on NM_015107.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); catalogued as rs1364840429, COSV57684102; called by muse, mutect2, varscan2
- TAF1 | c.4847C>T p.P1616L (on ENST00000373790 / NM_138923.4; = p.P1637L on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.244); catalogued as COSV99334320; called by muse, mutect2
- TRAF3IP1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs747690881; called by mutect2, varscan2
- TSHZ3 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs267605409; called by muse, mutect2, varscan2
- U2AF2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58272683; called by muse, mutect2, varscan2
- CLU | c.1219G>C p.V407L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- IGHD6-13 | c.20_21insGAGACC p.Y7delins* | Nonsense Mutation (INS) | VAF 39/44 reads (89%) | called by mutect2, pindel*, varscan2*
- LRFN5 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- MUC17 | c.8411C>T p.T2804I | Missense Mutation (SNP) | VAF 123/257 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- NOTCH4 | c.3736G>A p.E1246K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NSD2 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ACTL7A | c.984C>T p.I328= | Silent (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- BANK1 | c.1101A>G p.G367= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- KCNN1 | c.408T>G p.S136= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- ADH6 | chr4:99204125 A>G | 3'Flank (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- LMO3 | chr12:16605744 G>C | 5'Flank (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- POU2F2 | c.*70G>A | 3'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as rs578085962; called by muse, mutect2, varscan2
- RASSF4 | c.63-137C>A | Intron (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1490+110G>A | Intron (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- SYBU | chr8:109645443 G>A | 5'Flank (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- TMED10 | c.-25C>T | 5'UTR (SNP) | VAF 6/38 reads (16%) | catalogued as rs746420107; called by muse, mutect2
